Somatic mutation profile of tumor specimen TCGA-DE-A0XZ-01A (aliquot TCGA-DE-A0XZ-01A-11D-A17V-08) from TCGA case TCGA-DE-A0XZ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 65.8 years (24,020 days).
Specimen TCGA-DE-A0XZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4a80c17-acfe-4c99-8600-8a99a3bae0ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DE-A0XZ-10A (Blood Derived Normal), aliquot TCGA-DE-A0XZ-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ac6d0ab-ed3d-411a-8a92-bb31da1c4074

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAT1 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs754878846, COSV57186673; called by muse, mutect2, varscan2
- CNR2 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65692381, COSV65694779; called by muse, mutect2, varscan2
- COL3A1 | c.3169C>G p.P1057A | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.445); catalogued as rs768725737, COSV58597369; called by mutect2, varscan2
- CRP | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs763547558, COSV54814322; called by muse, mutect2, varscan2
- IGHM | c.755A>C p.Y252S | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.617); catalogued as rs782782140; called by muse, mutect2, varscan2
- KIR3DL1 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.074); catalogued as rs1460616438, COSV58496541; called by muse, mutect2, varscan2
- PDCD1LG2 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.121); catalogued as COSV67205596; called by muse, mutect2, varscan2
- PLIN5 | c.1315G>C p.G439R | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs372681667, COSV67851134; called by muse, mutect2, varscan2
- RSBN1L | c.2300T>C p.V767A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as COSV58507867; called by muse, mutect2, varscan2
- RXFP2 | c.1910C>A p.A637E | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53641451; called by muse, mutect2, varscan2
- SLC25A10 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as rs765499382, COSV58972082; called by muse, mutect2, varscan2
- TCEAL3 | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV54581534; called by muse, mutect2
- XRN1 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs746740206, COSV53818782; called by muse, mutect2, varscan2
- ZSCAN20 | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV63684709; called by muse, mutect2, varscan2
- LARP1 | c.2953+2dup p.X985_splice (on ENST00000518297 / NM_033551.3; = p.X908_splice on NM_015315.5 and 6 other RefSeq transcripts) | Splice Site (INS) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- MTTP | c.381A>C p.L127= | Silent (SNP) | VAF 4/87 reads (5%) | catalogued as COSV55510292; called by muse, mutect2
- SALL3 | c.2124G>A p.K708= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV73306644; called by muse, mutect2, varscan2
- STYXL2 | c.1521G>A p.R507= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs371011111, COSV54802738, COSV99609369; called by muse, mutect2, varscan2
- ZBED1 | c.1200C>T p.L400= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs377517735, COSV58139799; called by muse, mutect2, varscan2
